CCDI case PBCFBX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7173d167-4d2d-44b4-89e0-7c1374e4b930

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.9 years (5,430 days).

Biospecimens (3 samples)
- Sample 0DQU49: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQU4Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQU58: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
